Surgical pathology report (de-identified scan), TCGA case TCGA-YD-A9TA, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Spectrum Health, specimen TCGA-YD-A9TA-06A (Metastatic).

[page 1 of 2]
Research Gross Description

-year-old male who underwent wide local excision with sentinel lymph node mapping of a stage IB (pT2a pN0) malignant melanoma of the left posterior scalp in

Research Dx

A. Lung, left upper lobe, wedge resection:

Poorly differentiated malignant neoplasm, see comment.

COMMENT

Properly controlled immunohistochemical staining is performed and examined and is positive for vimentin, and negative for S100, melanoma cocktail, and pancytokeratin. The immunostaining profile is non-specific, and similar to the patient's previous pararenal mass, which was extensively worked up with immunohistochemical staining. Given the patient's history of melanoma, metastatic melanoma is favored.

Research QC

Tumor T:

90% tumor nuclei (consistent with melanoma)

5% necrosis

5% normal (lymphocytes)

200-0-3
Melanoma N6S 8720/3
Site @ Lung, upper lobe C34.1
JY 11/7/14

Research Specimen

-

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

Buffy coat frozen time:

Tissue:

Cold ischemia start time:

Formalin fixation start time:

Frozen start time:

Total cold ischemia time: 55 minutes

Formalin fixation stop time:

Total formalin fixation time: 16 hours

Specimen Weight

Plasma x 3

Serum x 2

Buffy coat x 1

Cryovials x 2

Normal x 0

Tumor x 0

Metastatic x 2

FFPE x 2

[page 2 of 2]
Normal x 0
Tumor x 0
Metastatic x 2

Specimen Size

Plasma x 3
Serum x 2
Buffy coat x 1

Cryovials x 2
Normal x 0
Tumor x 0
Metastatic x 2

FFPE x 2
Normal x 0
Tumor x 0
Metastatic x 2

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file 05457c78-ee82-4233-aa8e-40cd6c7957a0 (TCGA-YD-A9TA.1130D2F4-FABF-4F97-B6A0-23390E196305.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).